Surgical pathology report (de-identified scan), TCGA case TCGA-DW-5560, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-5560-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS: Kidney, right "mass" (excision): Renal cell carcinoma, papillary Type I. Incipient lesions are present, see Note.

NOTE: Immunohistochemical staining for CK7 is negative.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the Specialized [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: [REDACTED] with right renal mass. Specimen Taken For [REDACTED] Yes Allocate Order to Protocol: [REDACTED] 7

PROCEDURE: Operative Findings: right renal mass Post-Operative Diagnosis: right renal mass Pre-Operative Diagnosis: right renal mass

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Renal mass

GROSS DESCRIPTION: Received is a container labeled with the patient's name, medical record number, and "rt renal mass". The specimen is a partially encapsulated mass with a rim of renal parenchyma measuring 7.5 x 6 x 3.5 cm. The specimen is inked in black. Sectioning reveals a tan, soft cut surface with an eccentric red area with yellow area in it. Approximately 1 x 0.9 x 0.3 cm in aggregate of tumor tissue is procured for [REDACTED] (tumor nodule measures 2.5 cm in largest dimension). Procurement was performed by [REDACTED] [REDACTED]. After fixation, the tumor measures approximately 6.5 x 4.5 x 3.3 cm. Representative sections are taken and submitted in 8 white cassettes labeled [REDACTED] for permanent processing (2 pieces in E, 2 pieces in H, 2 pieces in I).

Patient Identification

[page 2 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Patient Identification

[REDACTED]

Source: NCI Genomic Data Commons file 745741a1-386d-4d75-ae22-6eb088a58e72 (TCGA-DW-5560.EA2661D6-B283-4B4F-98B4-80405B44CE17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).